Gene-level copy-number profile of tumor specimen TCGA-BA-4074-01A from TCGA case TCGA-BA-4074, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,282 days).
Specimen TCGA-BA-4074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e20f7423-4504-4421-b6d9-861f65220233.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-4074-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41c7a0ac-ee02-4175-ab94-2c6e18d6f0b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 17,682; copy number 2: 38,610; copy number 3: 2,630; copy number 4: 23; copy number 5: 80; copy number 6: 710; copy number 8: 14; copy number 9: 31; copy number 11: 8; copy number 15: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-4074-01A-01D-1432-01): tumor purity 0.61, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:30,292,548–30,527,193, 5 genes: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1.
- chr3:30,626,423–30,626,797, 1 gene: AC096921.1.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 868 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr11:68,891,276–71,928,654, 95 genes, copy number 5–15 (within-gene range 1–15) (broad region; genes not listed).
- chr18:22,213,778–25,818,532, 63 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
